Gene-level copy-number profile of tumor specimen TCGA-LN-A49K-01A from TCGA case TCGA-LN-A49K, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 66.7 years (24,379 days).
Specimen TCGA-LN-A49K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b57711b3-52fe-4767-9d33-c52d540a2bbd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/837f3367-89e2-4ad7-b6d7-c237c10b5e56

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 1,177; copy number 2: 18,841; copy number 3: 15,610; copy number 4: 19,540; copy number 5: 2,146; copy number 6: 639; copy number 7: 310; copy number 8: 1,369; copy number 9: 37; copy number 11: 59; copy number 12: 2; copy number 14: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49K-01A-11D-A246-01): tumor purity 0.66, ploidy 1.64, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:152,320,544–152,536,092, 4 genes (within-gene range 0–2): FBXW7, FBXW7-AS1, AC023424.2, MIR3140.
- chr9:20,999,509–23,438,700, 60 genes (within-gene range 0–4): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 117 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–118,713,678, 2 genes, copy number 12: PSMC1P12, AL139148.1.
- chr1:234,811,052–235,344,532, 16 genes, copy number 14: AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1.
- chr1:235,336,806–235,367,366, 3 genes, copy number 14: AL391994.1, AL357556.1, AL357556.5.
- chr3:153,881,526–158,871,821, 96 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 207. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
